Surgical pathology report (de-identified scan), TCGA case TCGA-BR-6563, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-6563-01A (Primary Tumor).

[page 1 of 2]
Formatted Path Report

STOMACH TISSUE CHECKLIST

Specimen type: Subtotal gastrectomy
Tumor site: Stomach
Tumor size: 5 x 3 x 1.5 cm
Tumor features: None specified
Histologic type: Adenocarcinoma
Histologic grade: Poorly differentiated
Tumor extent: Adjacent structures (specify) - lesser omentum
Lymph nodes: 1/3 positive for metastasis (Intraabdominal 1/3)
Lymphatic invasion: Not specified
Venous invasion: Not specified
Perineural invasion: Not specified
Margins: Not specified
Evidence of neo-adjuvant treatment: Not specified
Additional pathologic findings: Not specified
Comments: None

[page 2 of 2]
Date of Procurement

Source: NCI Genomic Data Commons file daed45cd-4aaf-4681-ac2f-7572bb0d0c27 (TCGA-BR-6563.A210204C-06E9-4D62-B8CB-72B42581CC09.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).